Somatic mutation profile of tumor specimen BA2718D (aliquot aq-BA2718D) from BEATAML1.0 case 2119, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.1 years (22,319 days).
Specimen BA2718D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad596755-637a-4e49-882e-ac9b6d792612.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2293D (Solid Tissue Normal), aliquot aq-BA2293D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f22cc1bd-c532-4888-860c-c68a892f5d12

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2
- KCNJ6 | c.559G>T p.G187* | Nonsense Mutation (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- OLFM1 | c.780C>A p.N260K (on ENST00000371793 / NM_001282611.2; = p.N242K on NM_014279.5) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.089); called by muse, mutect2
- RBM17 | c.681C>A p.S227R | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.037); called by muse, mutect2
- THOC2 | c.3318+1G>T p.X1106_splice | Splice Site (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- TICRR | c.4257C>A p.D1419E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.297); called by muse, mutect2
- ADRB3 | c.795G>T p.T265= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- LPIN1 | c.1350C>A p.G450= | Silent (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
